Somatic mutation profile of tumor specimen TCGA-AX-A1CA-01A (aliquot TCGA-AX-A1CA-01A-12D-A135-09) from TCGA case TCGA-AX-A1CA, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 70.7 years (25,817 days).
Specimen TCGA-AX-A1CA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 650ef12b-bc52-4a3e-a5f7-9609f5054161.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A1CA-10A (Blood Derived Normal), aliquot TCGA-AX-A1CA-10A-01D-A135-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/86433f6f-93ff-4378-a790-b951cc5c8a76

The open-access MAF lists 122 somatic variants for this specimen: 88 protein-altering or splice-affecting, 32 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 32, Nonsense Mutation 7, Frame Shift Del 3, Frame Shift Ins 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 19/36 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AFDN | c.4805G>T p.R1602I | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); catalogued as COSV100653241; called by muse, mutect2, varscan2
- ALG6 | c.970G>T p.G324* | Nonsense Mutation (SNP) | VAF 13/75 reads (17%) | catalogued as COSV99673352; called by muse, mutect2, varscan2
- AMY2A | c.302G>A p.C101Y | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101340654; called by muse, mutect2
- ANGPTL2 | c.1196G>A p.R399H | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.168); catalogued as rs764497308, COSV52216437; called by muse, mutect2, varscan2
- APOBEC3G | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.019); catalogued as COSV101349093; called by muse, mutect2
- ASAP2 | c.2923G>A p.G975R | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.455); catalogued as rs373040649, COSV99432093; called by muse, mutect2, varscan2
- ATP5PB | c.598C>G p.H200D | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV100867647; called by muse, mutect2, varscan2
- AUTS2 | c.3008C>T p.S1003L | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as rs543645962; called by muse, mutect2
- C10orf71 | c.2047G>C p.E683Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.467); catalogued as COSV100110411, COSV60507522; called by muse, mutect2, varscan2
- CACNA1S | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.138); catalogued as COSV100755190; called by muse, mutect2, varscan2
- CCDC87 | c.1546G>C p.E516Q | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376754440, COSV100039693; called by mutect2, varscan2
- CDHR1 | c.1105G>C p.E369Q | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100259174; called by muse, mutect2, varscan2
- CHFR | c.1201G>A p.E401K (on ENST00000432561 / NM_001161345.1; = p.E360K on NM_018223.2) | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99905525; called by muse, mutect2, varscan2
- CREB5 | c.139C>A p.P47T (on ENST00000357727 / NM_182898.4; = p.P40T on NM_004904.3) | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.085); catalogued as COSV100745070, COSV63221094; called by muse, mutect2, varscan2
- CYP2A13 | c.259G>A p.V87I | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.395); catalogued as rs753958154, COSV100386917; called by muse, mutect2, varscan2
- DNAH5 | c.6382G>A p.V2128I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs754976621, COSV54239412; called by muse, mutect2, varscan2
- EP300 | c.4570G>A p.E1524K | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54326530; called by muse, mutect2, varscan2
- ERAP1 | c.2023C>T p.Q675* | Nonsense Mutation (SNP) | VAF 28/81 reads (35%) | catalogued as rs1338734153, COSV99701126; called by muse, mutect2, varscan2
- FAM227B | c.838G>C p.E280Q | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV100175344; called by muse, mutect2, varscan2
- FAR1 | c.1232A>G p.N411S | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100701615; called by muse, mutect2, varscan2
- FBN1 | c.3248G>C p.R1083T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.052); catalogued as COSV100355887; called by muse, mutect2, varscan2
- FLT3 | c.541G>T p.A181S | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.034); catalogued as rs750445891, COSV54045682, COSV54071115; called by muse, mutect2, varscan2
- FOXP1 | c.827C>G p.S276C | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs766384570, COSV100562026; called by muse, mutect2, varscan2
- FOXR1 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100392964; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.332A>T p.K111M | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.326); catalogued as COSV100599036; called by muse, mutect2
- GAL3ST4 | c.322C>A p.P108T | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99444889; called by muse, mutect2, varscan2
- GON4L | c.4640A>G p.E1547G | Missense Mutation (SNP) | VAF 53/107 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.417); catalogued as COSV99675073; called by muse, mutect2, varscan2
- GORAB | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV100883773; called by muse, mutect2, varscan2
- GRID1 | c.1776G>C p.Q592H | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV60037490; called by muse, mutect2
- GRM5 | c.2098C>T p.L700F | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100553219; called by muse, mutect2, varscan2
- GTF3C1 | c.963G>C p.K321N | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV100649587, COSV100649642; called by muse, mutect2, varscan2
- HECTD1 | c.2603C>A p.S868* | Nonsense Mutation (SNP) | VAF 13/39 reads (33%) | catalogued as COSV65991173; called by muse, mutect2, varscan2
- HPSE2 | c.1501A>T p.I501F | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100986026; called by muse, mutect2, varscan2
- IDE | c.2026G>A p.E676K | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV99794178; called by muse, mutect2, varscan2
- IFNL2 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.163); catalogued as COSV100122107, COSV59593254; called by muse, mutect2
- IGSF5 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs765868442, COSV101012153, COSV66030416; called by muse, mutect2, varscan2
- INTS5 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1161703016, COSV100399720; called by muse, mutect2, varscan2
- ITGA11 | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747868028, COSV100241911; called by muse, mutect2, varscan2
- JMY | c.1825C>G p.L609V | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101268075; called by muse, mutect2, varscan2
- KCNT2 | c.29del p.P10Lfs*13 | Frame Shift Del (DEL) | VAF 10/105 reads (10%) | catalogued as COSV54094487; called by pindel, varscan2
- KIF2B | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.479); catalogued as rs754482684, COSV52128242; called by muse, mutect2, varscan2
- LIN54 | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100464836; called by muse, mutect2
- LMAN1 | c.584G>A p.R195H | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755799692, COSV51826827, COSV99195313; called by muse, mutect2, varscan2
- LPIN2 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99858654; called by muse, mutect2, varscan2
- MICAL1 | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 29/76 reads (38%) | catalogued as rs375429113; called by muse, mutect2, varscan2
- MUSK | c.799G>T p.D267Y | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV99504667; called by muse, mutect2, varscan2
- MYC | c.1076A>G p.H359R (on ENST00000377970; = p.H374R on NM_002467.6) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52367783; called by muse, mutect2, varscan2
- MYO18B | c.3761G>A p.R1254H | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs774090650, COSV59124937, COSV59152211; called by muse, mutect2, varscan2
- NHLRC2 | c.2074G>C p.D692H | Missense Mutation (SNP) | VAF 55/108 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as COSV100992985; called by muse, mutect2, varscan2
- NLRP5 | c.124C>A p.Q42K | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV101173595; called by muse, mutect2, varscan2
- NPHP3 | c.2002C>T p.H668Y | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as COSV100447123; called by muse, mutect2, varscan2
- NUP62 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.306); catalogued as rs142980354; called by muse, mutect2, varscan2
- OSGIN2 | c.107C>G p.S36* | Nonsense Mutation (SNP) | VAF 30/83 reads (36%) | catalogued as COSV99858498; called by muse, mutect2, varscan2
- PACSIN3 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 18/23 reads (78%) | catalogued as rs919199703, COSV100096472; called by muse, mutect2, varscan2
- PCOLCE | c.937C>G p.P313A | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs926932445, COSV99775276; called by muse, mutect2, varscan2
- PCYOX1L | c.1247C>T p.S416L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.212); catalogued as COSV99199224; called by muse, mutect2, varscan2
- PGLYRP4 | c.673C>T p.H225Y | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as COSV100668469; called by muse, mutect2
- PHC1 | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101418667, COSV70418003; called by muse, mutect2, varscan2
- PLVAP | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99391481; called by muse, mutect2, varscan2
- PRAM1 | c.1544G>T p.R515I | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV99725714; called by muse, mutect2, varscan2
- PTPRB | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.217); catalogued as rs1239383943, COSV99718190; called by muse, varscan2
- PTPRN2 | c.291G>T p.Q97H | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.819); catalogued as COSV101234968; called by muse, mutect2
- QRSL1 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs1028223547, COSV64689783; called by muse, mutect2, varscan2
- RAB11FIP1 | c.997G>T p.G333C | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV54761216, COSV99770291; called by muse, mutect2
- RAB40C | c.490A>T p.I164F | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.317); catalogued as COSV99937885; called by muse, mutect2, varscan2
- RIMS1 | c.3491G>T p.R1164I | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.981); catalogued as COSV53487707, COSV99328652; called by muse, mutect2, varscan2
- RPL7 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as COSV99536400; called by muse, mutect2, varscan2
- SLC6A13 | c.55C>A p.P19T | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs748228106, COSV100570010; called by muse, mutect2, varscan2
- SPOP | c.590C>A p.S197Y | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.598); catalogued as COSV100753475, COSV61654801; called by muse, mutect2, varscan2
- SPTA1 | c.4196T>A p.M1399K | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV100935238, COSV63751636; called by muse, mutect2, varscan2
- TCP11L1 | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV100178253; called by muse, mutect2, varscan2
- TMEM106B | c.438C>G p.I146M | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.061); catalogued as COSV101188848; called by muse, varscan2
- TRIM51 | c.494C>T p.T165I | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99792917; called by muse, mutect2, varscan2
- TRIO | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs769526836, COSV60095903; called by muse, mutect2, varscan2
- TUBB6 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.113); catalogued as rs940484159, COSV52314076; called by muse, mutect2, varscan2
- ULK1 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV58857015; called by muse, varscan2
- USP15 | c.253G>A p.D85N | Missense Mutation (SNP) | VAF 5/80 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1436174465, COSV99740136; called by muse, mutect2
- UTP20 | c.3481G>C p.D1161H | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99882070; called by muse, mutect2, varscan2
- VDAC1 | c.361G>T p.E121* | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV99527281; called by muse, mutect2, varscan2
- WNT10B | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as COSV56405882, COSV99975709; called by muse, mutect2, varscan2
- YY1AP1 | c.1177G>A p.D393N (on ENST00000295566 / NM_139118.2; = p.D336N on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 72/151 reads (48%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.932); catalogued as COSV99804391; called by muse, mutect2, varscan2
- ZFP36L2 | c.662G>A p.R221Q | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.886); catalogued as rs1205779063, COSV99144007; called by muse, mutect2
- ZNF490 | c.908A>G p.E303G | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100267439; called by muse, mutect2, varscan2
- ZSWIM4 | c.865C>G p.R289G | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV99585131; called by muse, mutect2, varscan2
- LRP2BP | c.980dup p.C328Lfs*10 | Frame Shift Ins (INS) | VAF 14/39 reads (36%) | called by mutect2, pindel, varscan2
- RNF212 | c.490_493del p.S164Lfs*9 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- TMEM106B | c.345_346del p.L116Ffs*20 | Frame Shift Del (DEL) | VAF 90/326 reads (28%) | called by pindel, varscan2
- ADAMTS10 | c.456C>T p.D152= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as rs371629978; called by muse, mutect2, varscan2
- ADGRF5 | c.2595C>G p.T865= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV99346040; called by muse, mutect2, varscan2
- AIFM1 | c.1473C>A p.G491= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as COSV99781212; called by muse, mutect2
- ATP5F1B | c.1452G>T p.L484= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV99466936; called by muse, mutect2, varscan2
- AZI2 | c.501G>A p.L167= | Silent (SNP) | VAF 6/148 reads (4%) | catalogued as COSV99843704; called by muse, mutect2
- CDH7 | c.1368G>A p.E456= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV100542839; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.873G>A p.S291= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs145187250; called by muse, mutect2, varscan2
- CIT | c.5958C>T p.L1986= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV99950315; called by muse, mutect2
- CLTA | c.36C>T p.G12= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as rs1295946559, COSV99643667; called by muse, mutect2
- CNNM2 | c.2154G>C p.L718= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as COSV100881874; called by muse, mutect2, varscan2
- DNAH2 | c.1344C>G p.V448= | Silent (SNP) | VAF 36/48 reads (75%) | catalogued as COSV99318356; called by muse, mutect2, varscan2
- DNAJB13 | c.948A>G p.T316= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs1175910935, COSV100135112; called by muse, mutect2, varscan2
- FZD4 | c.111C>T p.F37= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as rs1265604791, COSV101536061; called by muse, mutect2, varscan2
- GLDC | c.1737C>A p.I579= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100394352, COSV100394458; called by muse, mutect2, varscan2
- H2BC12 | c.60T>C p.T20= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV100804718; called by muse, mutect2
- HECTD4 | c.7788C>T p.G2596= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as rs769327415, COSV101108027; called by muse, mutect2, varscan2
- HRNR | c.477G>C p.L159= | Silent (SNP) | VAF 50/121 reads (41%) | catalogued as COSV100913704; called by muse, mutect2, varscan2
- KCNA6 | c.927C>T p.I309= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV54974048; called by muse, mutect2, varscan2
- KDM4A | c.2424C>T p.V808= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV100969563; called by muse, mutect2, varscan2
- KIAA1210 | c.4080C>T p.S1360= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs748409844, COSV101274308; called by muse, mutect2, varscan2
- MARCHF6 | c.1071G>T p.V357= | Silent (SNP) | VAF 30/158 reads (19%) | catalogued as COSV99929991; called by muse, mutect2, varscan2
- MC2R | c.855C>T p.D285= | Silent (SNP) | VAF 17/62 reads (27%) | catalogued as rs199501141, COSV59618663; called by muse, mutect2, varscan2
- NES | c.1335G>A p.E445= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100957933; called by muse, mutect2, varscan2
- NFIC | c.1047C>T p.F349= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV100545533; called by muse, mutect2, varscan2
- OR5B17 | c.585G>A p.L195= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100641872, COSV62161144; called by muse, mutect2, varscan2
- OR8J1 | c.450C>T p.L150= | Silent (SNP) | VAF 32/169 reads (19%) | catalogued as COSV100275111; called by muse, mutect2, varscan2
- PROKR1 | c.708C>T p.I236= | Silent (SNP) | VAF 24/49 reads (49%) | catalogued as COSV58136600; called by muse, mutect2, varscan2
- RAD23A | c.1011C>T p.V337= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV100380310; called by muse, mutect2, varscan2
- RLBP1 | c.258G>A p.E86= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV51528817; called by muse, mutect2, varscan2
- TTN | c.13869T>C p.D4623= (on ENST00000591111; = p.D3696= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV100621252; called by muse, mutect2, varscan2
- TUBA3C | c.909C>G p.V303= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV101262812; called by muse, mutect2
- ZCCHC7 | c.36C>T p.Y12= | Silent (SNP) | VAF 33/123 reads (27%) | catalogued as rs756127706, COSV100383317, COSV100383568; called by muse, mutect2, varscan2
- ERCC6 | c.1397+7220C>T | Intron (SNP) | VAF 16/112 reads (14%) | catalogued as COSV100876039; called by muse, mutect2, varscan2
- POM121C | chr7:75416180 G>A | 3'Flank (SNP) | VAF 4/36 reads (11%) | catalogued as rs781787812; called by muse, mutect2
